Somatic mutation profile of tumor specimen 0DKFA2 from CCDI case PBBYAL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,105 days).
Specimen 0DKFA2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d7e403a-1363-41d9-b650-ec628959eba8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fef67a5-5a52-4f8e-a4e4-f1e1c6a5626f

The open-access MAF lists 261 somatic variants for this specimen: 163 protein-altering or splice-affecting, 64 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 64, Intron 18, Nonsense Mutation 11, 3'UTR 9, Splice Region 5, 5'UTR 3, RNA 2, Splice Site 2, In Frame Ins 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCSK9 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 254/621 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1254346075, COSV56162369; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 191/920 reads (21%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 264/525 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAP2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 325/645 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261551676; called by muse, mutect2, varscan2
- ANO9 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 150/630 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs530624536, COSV60383247; called by muse, mutect2, varscan2
- AP1M2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 224/516 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751078224, COSV99140876; called by muse, mutect2, varscan2
- ATRX | c.6563G>A p.R2188Q | Missense Mutation (SNP) | VAF 44/788 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64879508, COSV64879971; called by muse, mutect2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 148/731 reads (20%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- BRD1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 167/375 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs749493364; called by muse, mutect2, varscan2
- BRWD3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 368/696 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs1064796915, COSV64751743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C2orf73 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 82/794 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.144); catalogued as rs774467569, COSV58310813; called by muse, mutect2, varscan2
- C3orf20 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 302/678 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.43); catalogued as rs763094982, COSV99514662; called by muse, mutect2, varscan2
- CACHD1 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 174/771 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs754629617, COSV51549780; called by muse, mutect2, varscan2
- CATSPER1 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs749940054; called by muse, mutect2, varscan2
- CDK9 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373394121; called by muse, mutect2, varscan2
- CEP170B | c.4214G>A p.R1405Q (on ENST00000453495; = p.R1334Q on NM_015005.3) | Missense Mutation (SNP) | VAF 359/660 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs778584880; called by muse, mutect2, varscan2
- CLCN7 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 104/564 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.201); catalogued as rs367805626; called by muse, mutect2, varscan2
- CLK2 | c.413G>A p.R138Q (on ENST00000368361 / NM_001294339.2; = p.R137Q on NM_003993.4) | Missense Mutation (SNP) | VAF 48/1012 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1477026654, COSV62877709; called by muse, mutect2
- CLSTN3 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 133/543 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs751373748, COSV56941249; called by muse, mutect2, varscan2
- CNBD2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 177/847 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs200885142, COSV62586786; called by muse, mutect2, varscan2
- CSMD2 | c.4513C>T p.R1505W | Missense Mutation (SNP) | VAF 35/913 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs867644442, COSV53976721; called by muse, mutect2
- CSNK1D | c.885+8G>A | Splice Region (SNP) | VAF 336/723 reads (46%) | catalogued as rs561610034, COSV53924511; called by muse, mutect2, varscan2
- CTNND2 | c.2731G>A p.A911T | Missense Mutation (SNP) | VAF 429/958 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1188686094, COSV58895657; called by muse, mutect2, varscan2
- DBNL | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 99/783 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs759801390, COSV68883029, COSV68883035; called by muse, mutect2, varscan2
- DDX43 | c.1007G>A p.C336Y | Missense Mutation (SNP) | VAF 171/955 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1425114250; called by muse, mutect2, varscan2
- DHX29 | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 321/781 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs755075998, COSV52418186; called by muse, mutect2, varscan2
- DLGAP1 | c.2029G>A p.V677M | Missense Mutation (SNP) | VAF 105/655 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs757116022, COSV59843045; called by muse, mutect2, varscan2
- DNAH10 | c.13099C>T p.R4367W (on ENST00000409039; = p.R4306W on NM_207437.3) | Missense Mutation (SNP) | VAF 76/552 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs758717755, COSV53018474, COSV53020168; called by muse, mutect2, varscan2
- DNHD1 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 208/816 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs267603117; called by muse, mutect2, varscan2
- DNM1L | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 43/1324 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs905283579; called by muse, mutect2
- DYSF | c.2833G>A p.G945S | Missense Mutation (SNP) | VAF 68/918 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763298311, COSV99246339; called by muse, mutect2
- ELOVL4 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 21/598 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1554162016, COSV100876167; ClinVar: uncertain significance; called by muse, mutect2
- ERV3-1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 165/599 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as rs566324998, COSV51426735; called by muse, mutect2, varscan2
- EZHIP | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 25/614 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs782507486; called by muse, mutect2
- EZHIP | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 164/570 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs1423163127; called by muse, mutect2, varscan2
- F7 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121964930, CM960534, COSV100660964; called by muse, mutect2, varscan2
- FAM204A | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 33/608 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV64987991; called by muse, mutect2
- FAM83B | c.1067A>G p.H356R | Missense Mutation (SNP) | VAF 74/732 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV60924614; called by muse, mutect2, varscan2
- FAT1 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 216/496 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs143694311; called by muse, mutect2, varscan2
- FSCN3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs768392595; called by muse, mutect2, varscan2
- GABBR1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 210/1164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1028329001; called by muse, mutect2, varscan2
- GLI3 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 214/711 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs377579354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNG3 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 328/630 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1064797156, COSV53655795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA3 | c.3146C>T p.A1049V | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs181642584; called by muse, mutect2, varscan2
- GPR174 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 58/901 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766754517, COSV52133215, COSV52133712; called by muse, mutect2
- GTF3C1 | c.3302G>A p.R1101H | Missense Mutation (SNP) | VAF 132/245 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs199791720; called by muse, mutect2, varscan2
- GZMB | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 125/548 reads (23%) | catalogued as rs369959551; called by muse, mutect2, varscan2
- H1-6 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 383/895 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs757233893, COSV58091666; called by muse, mutect2, varscan2
- H6PD | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs1384664557; called by muse, mutect2, varscan2
- HERC1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 282/741 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs370923299; called by muse, mutect2, varscan2
- HHATL | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 108/592 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1056662803, COSV104382496; called by muse, mutect2, varscan2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 190/518 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, mutect2, varscan2
- ICAM1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763586600, COSV53427637; called by muse, mutect2, varscan2
- IPO5 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 262/529 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs369366204; called by muse, mutect2, varscan2
- JPH2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 48/872 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV65904077; called by muse, mutect2
- KCNQ2 | c.2108C>T p.A703V (on ENST00000359125 / NM_172107.4; = p.A675V on NM_004518.6) | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs779430808; called by muse, varscan2
- KDM5A | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 34/793 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV66997327; called by muse, mutect2
- KIF22 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 276/633 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs776122940; called by muse, mutect2, varscan2
- KIN | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 227/575 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs376639368; called by muse, mutect2, varscan2
- KLK12 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 224/495 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.121); catalogued as rs762968082, COSV99142118; called by muse, mutect2, varscan2
- KMT2B | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 161/599 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs769921695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAYN | c.790C>T p.R264W (on ENST00000375615 / NM_001258390.1; = p.R256W on NM_178834.5) | Missense Mutation (SNP) | VAF 248/568 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs773587902, COSV100986216; called by muse, mutect2, varscan2
- LRRC37A3 | c.3172+1G>A p.X1058_splice | Splice Site (SNP) | VAF 70/1210 reads (6%) | catalogued as rs139954718, COSV58536216; called by muse, mutect2
- MBD6 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 42/690 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.867); catalogued as rs751486226, COSV100851637; called by muse, mutect2
- MED12 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 151/602 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61335886; called by muse, varscan2
- MISP | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 133/279 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145115054, COSV99297200; called by muse, mutect2, varscan2
- MSR1 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 204/881 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774834555, COSV50507879; called by muse, mutect2, varscan2
- MUC4 | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.101); catalogued as rs750630374, COSV62165854; called by muse, mutect2
- MXRA5 | c.8152G>A p.G2718S | Missense Mutation (SNP) | VAF 158/251 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373522683; called by muse, mutect2, varscan2
- NAB2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs776347211, COSV55666003; called by muse, mutect2, varscan2
- NCOA6 | c.5639C>T p.T1880M | Missense Mutation (SNP) | VAF 161/494 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.828); catalogued as rs760455129; called by muse, mutect2, varscan2
- NFASC | c.3018C>T p.S1006= | Splice Region (SNP) | VAF 227/435 reads (52%) | catalogued as rs866537431; called by muse, mutect2, varscan2
- NISCH | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 308/692 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100617346; called by muse, mutect2, varscan2
- NUDT1 | c.355G>A p.V119M (on ENST00000397048 / NM_198952.1; = p.V96M on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/668 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs756492763; called by muse, mutect2
- NUP133 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 355/829 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1226411572; called by muse, mutect2, varscan2
- NXPH1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 318/1181 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs1274208163, COSV101339717; called by muse, mutect2, varscan2
- OBSL1 | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 280/574 reads (49%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.691); catalogued as rs368874304; called by muse, mutect2, varscan2
- OXCT1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 459/1123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM074399, COSV52173608; called by muse, mutect2, varscan2
- P2RY2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 115/226 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs774131631, COSV60777677; called by muse, mutect2, varscan2
- PASK | c.3358C>T p.R1120C | Missense Mutation (SNP) | VAF 27/714 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1375013740, COSV52154899; called by muse, mutect2
- PCGF6 | c.967C>T p.R323* (on ENST00000369847 / NM_001011663.2; = p.R248* on NM_032154.4) | Nonsense Mutation (SNP) | VAF 58/458 reads (13%) | catalogued as rs1348440593, COSV61494346, COSV61495322; called by muse, mutect2, varscan2
- PCLO | c.13246C>T p.R4416C | Missense Mutation (SNP) | VAF 225/879 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772144520, COSV100431464, COSV100436157; called by muse, mutect2, varscan2
- PEAK1 | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 43/997 reads (4%) | catalogued as COSV100432636; called by muse, mutect2
- PELP1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439876197; called by muse, mutect2
- PKD1L1 | c.6074G>A p.R2025Q | Missense Mutation (SNP) | VAF 227/913 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs372219419; called by muse, mutect2, varscan2
- PPM1H | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 236/520 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs780498734; called by muse, mutect2, varscan2
- PRKCG | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 36/1110 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV54728119; called by muse, mutect2
- QSER1 | c.551G>A p.R184Q (on ENST00000399302; = p.R313Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 156/602 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200602989, COSV101234908; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 285/636 reads (45%) | catalogued as rs756946687; called by mutect2, varscan2
- RRM2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 62/1658 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.59); catalogued as rs1319074724; called by muse, mutect2
- SALL4 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 216/809 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs749395357, COSV53852602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SARM1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 38/696 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs369804438; called by muse, mutect2
- SCFD2 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 308/643 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1402682368, COSV101189293; called by muse, mutect2, varscan2
- SCGB1C1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 130/1510 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1348013308; called by muse, mutect2
- SETSIP | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 100/1579 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as rs576393406; called by muse, mutect2
- SEZ6L2 | c.1004G>A p.R335Q (on ENST00000308713 / NM_001114099.3; = p.R265Q on NM_012410.4) | Missense Mutation (SNP) | VAF 94/486 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs556280590, COSV58103023; called by muse, mutect2, varscan2
- SFSWAP | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 253/605 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs373461589; called by muse, mutect2, varscan2
- SGMS2 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 198/896 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs534700067; called by muse, mutect2, varscan2
- SGSM1 | c.801G>A p.P267= | Splice Region (SNP) | VAF 294/727 reads (40%) | catalogued as rs767115692; called by muse, varscan2
- SH3PXD2B | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 58/1010 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100288582; called by muse, mutect2
- SHANK3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 25/750 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.382); catalogued as rs951331050; called by muse, mutect2
- SHPRH | c.3866G>A p.R1289Q (on ENST00000275233 / NM_001042683.3; = p.R1293Q on NM_173082.3) | Missense Mutation (SNP) | VAF 52/1158 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV99262430, COSV99262786; called by muse, mutect2
- SKI | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 44/800 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1416321268; called by muse, mutect2
- SLC18A2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 499/970 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs756722746, COSV53688287; called by muse, mutect2, varscan2
- SLC30A8 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 172/742 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145677283; called by muse, mutect2, varscan2
- SLC4A2 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 30/686 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275160083, COSV59657856; called by muse, mutect2
- SMC2 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 77/1222 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as rs772576514, COSV53963495; called by muse, mutect2
- SPTBN5 | c.5984G>A p.R1995Q | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs371908812; called by muse, mutect2, varscan2
- STXBP5L | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 110/641 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257841186, COSV99873846; called by muse, mutect2, varscan2
- SUCLG1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 45/782 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs201224138; ClinVar: uncertain significance; called by muse, mutect2
- SURF4 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 30/668 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV64332080; called by muse, mutect2
- TAAR6 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 324/816 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV51582981, COSV51584482; called by muse, mutect2, varscan2
- TAOK3 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 385/917 reads (42%) | catalogued as rs764673249; called by muse, mutect2, varscan2
- TECTA | c.4510C>T p.R1504C | Missense Mutation (SNP) | VAF 48/780 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs727505218, COSV50690411; ClinVar: uncertain significance; called by muse, mutect2
- TP53BP1 | c.5044C>T p.R1682* | Nonsense Mutation (SNP) | VAF 289/690 reads (42%) | catalogued as rs746063219; called by muse, mutect2, varscan2
- TRRAP | c.3646C>T p.R1216W | Missense Mutation (SNP) | VAF 268/1059 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs757085445, COSV62838590; called by muse, mutect2, varscan2
- UBR5 | c.6206G>A p.R2069H | Missense Mutation (SNP) | VAF 230/1047 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs746654796; called by muse, mutect2, varscan2
- WDR33 | c.2467G>A p.G823S | Missense Mutation (SNP) | VAF 272/539 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as rs369184370; called by muse, mutect2, varscan2
- WNT5B | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 58/1016 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs367856456; called by muse, mutect2
- ZBTB21 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 381/881 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs181765349, COSV60405882; called by muse, mutect2, varscan2
- ZNF197 | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 313/697 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs769234925; called by muse, mutect2, varscan2
- ZNF768 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 206/493 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); catalogued as rs1354344689; called by muse, mutect2, varscan2
- ZNF787 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 25/514 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as rs1182506718; called by muse, mutect2
- ATP9A | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 30/1043 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 200/692 reads (29%) | called by mutect2, varscan2
- C5orf47 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 23/605 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.223); called by muse, mutect2
- CACNA1A | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CCDC141 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 34/1028 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- CDC42SE1 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 28/614 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CDCA7L | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 50/1719 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- CELF2 | c.1273C>T p.L425F (on ENST00000416382 / NM_001025077.3; = p.L438F on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/896 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CELF6 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CREBZF | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 25/491 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2
- DBN1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 59/357 reads (17%) | called by muse, mutect2, varscan2
- DGKB | c.1783A>G p.I595V | Missense Mutation (SNP) | VAF 367/1381 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH2 | c.6222G>T p.K2074N | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ESX1 | c.1148A>T p.H383L | Missense Mutation (SNP) | VAF 46/607 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- FAM13B | c.2374G>A p.G792S | Missense Mutation (SNP) | VAF 211/507 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FMO3 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 28/639 reads (4%) | called by muse, mutect2
- GIGYF2 | c.2881C>T p.R961* | Nonsense Mutation (SNP) | VAF 377/837 reads (45%) | called by muse, mutect2, varscan2
- HNRNPF | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 198/886 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, varscan2
- ICE1 | c.6710C>A p.A2237D | Missense Mutation (SNP) | VAF 219/926 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- KANSL2 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 47/730 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.296); called by muse, mutect2
- KIF12 | c.658C>T p.R220* (on ENST00000640217; = p.R82* on NM_138424.1) | Nonsense Mutation (SNP) | VAF 76/366 reads (21%) | called by muse, mutect2, varscan2
- LTBP3 | c.3493C>T p.R1165C (on ENST00000301873 / NM_001130144.3; = p.R1118C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/483 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K6 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAPKBP1 | c.1685C>T p.T562M (on ENST00000456763 / NM_001128608.2; = p.T556M on NM_014994.3) | Missense Mutation (SNP) | VAF 26/649 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGST2 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 51/1266 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); called by muse, mutect2
- MSH6 | c.3797_3799dup p.H1266_M1267insN | In Frame Ins (INS) | VAF 294/645 reads (46%) | called by mutect2, varscan2
- NELFCD | c.1157G>A p.S386N (on ENST00000602795; = p.S368N on NM_198976.4) | Missense Mutation (SNP) | VAF 77/1352 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- POLA1 | c.3613A>T p.T1205S | Missense Mutation (SNP) | VAF 38/814 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- RALGAPA2 | c.5449A>G p.N1817D | Missense Mutation (SNP) | VAF 187/1161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RAVER1 | c.1261+5C>T | Splice Region (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- RB1 | c.2255T>C p.I752T | Missense Mutation (SNP) | VAF 228/545 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP4 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 45/745 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- RHOXF2 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 74/759 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCGB1C2 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SNCA | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 356/841 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SYNJ2 | c.1524G>A p.L508= | Splice Region (SNP) | VAF 54/591 reads (9%) | called by muse, mutect2
- TRAK2 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2
- VPS37A | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 185/796 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZCCHC14 | c.1333+1G>A p.X445_splice (on ENST00000268616; = p.X582_splice on NM_015144.3) | Splice Site (SNP) | VAF 26/856 reads (3%) | called by muse, mutect2
- ZNF831 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 39/461 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- ACTRT2 | c.12G>A p.P4= | Silent (SNP) | VAF 156/307 reads (51%) | catalogued as rs774900733, COSV65760661; called by muse, mutect2, varscan2
- AMPD1 | c.1578C>T p.P526= | Silent (SNP) | VAF 383/807 reads (47%) | called by muse, mutect2, varscan2
- ANXA11 | c.1431C>T p.Y477= | Silent (SNP) | VAF 199/467 reads (43%) | called by muse, mutect2, varscan2
- BAHCC1 | c.7155G>T p.P2385= | Silent (SNP) | VAF 20/394 reads (5%) | called by muse, mutect2
- BAMBI | c.468C>T p.A156= | Silent (SNP) | VAF 355/837 reads (42%) | catalogued as rs552025432; called by muse, mutect2, varscan2
- BCL7A | c.204C>T p.D68= | Silent (SNP) | VAF 223/548 reads (41%) | catalogued as rs188720973, COSV55848340; called by muse, mutect2, varscan2
- BORA | c.828C>T p.N276= (on ENST00000613797; = p.N201= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 300/772 reads (39%) | catalogued as rs753954993; called by muse, mutect2, varscan2
- BPIFB6 | c.48G>A p.T16= | Silent (SNP) | VAF 370/1167 reads (32%) | catalogued as rs774189878, COSV62756674; called by muse, mutect2, varscan2
- C2orf16 | c.1800C>T p.I600= | Silent (SNP) | VAF 319/742 reads (43%) | catalogued as rs760184570, COSV62674483; called by muse, mutect2, varscan2
- CACNA1H | c.4812G>A p.S1604= | Silent (SNP) | VAF 62/780 reads (8%) | catalogued as rs377611664; called by muse, mutect2
- CAMKK1 | c.774C>T p.D258= | Silent (SNP) | VAF 87/553 reads (16%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1323C>T p.V441= | Silent (SNP) | VAF 52/346 reads (15%) | called by muse, mutect2, varscan2
- CC2D1A | c.657G>A p.A219= | Silent (SNP) | VAF 236/508 reads (46%) | catalogued as rs367628101; called by muse, mutect2, varscan2
- CLCN2 | c.2682C>T p.D894= | Silent (SNP) | VAF 161/872 reads (18%) | catalogued as rs747140888; called by muse, mutect2, varscan2
- CLN3 | c.1116C>T p.I372= (on ENST00000360019 / NM_001286104.2; = p.I396= on NM_000086.2) | Silent (SNP) | VAF 62/699 reads (9%) | catalogued as rs926869261; called by muse, mutect2
- COMP | c.1593C>T p.F531= | Silent (SNP) | VAF 29/562 reads (5%) | catalogued as COSV55874377; called by muse, mutect2
- CRTC1 | c.1254G>A p.P418= | Silent (SNP) | VAF 26/484 reads (5%) | catalogued as rs964491069; called by muse, mutect2
- CYP2D6 | c.1005C>T p.I335= | Silent (SNP) | VAF 28/494 reads (6%) | catalogued as rs199980688, COSV62246014; called by muse, mutect2
- DGKK | c.3216C>T p.D1072= | Silent (SNP) | VAF 433/740 reads (59%) | catalogued as rs782341862; called by muse, mutect2, varscan2
- DMBT1 | c.7569C>T p.D2523= (on ENST00000338354 / NM_001377530.1; = p.D1766= on NM_004406.3) | Silent (SNP) | VAF 241/574 reads (42%) | catalogued as rs201579246, COSV57539698; called by muse, mutect2, varscan2
- DOCK5 | c.4023C>T p.L1341= | Silent (SNP) | VAF 159/719 reads (22%) | called by muse, mutect2, varscan2
- EHMT2 | c.2934C>T p.D978= | Silent (SNP) | VAF 196/433 reads (45%) | catalogued as rs776033749; called by muse, mutect2, varscan2
- GRIK3 | c.1233C>T p.A411= | Silent (SNP) | VAF 340/719 reads (47%) | catalogued as rs780733115; called by muse, mutect2, varscan2
- IGSF10 | c.3537G>A p.S1179= | Silent (SNP) | VAF 422/909 reads (46%) | catalogued as rs181702818; called by muse, mutect2, varscan2
- KIAA0408 | c.2031G>A p.R677= | Silent (SNP) | VAF 70/1382 reads (5%) | catalogued as rs1183213082, COSV100847535; called by muse, mutect2
- KIAA1549 | c.4920C>T p.I1640= | Silent (SNP) | VAF 130/896 reads (15%) | catalogued as rs756943187, COSV54312018; called by muse, mutect2, varscan2
- LAMB1 | c.3498G>A p.T1166= | Silent (SNP) | VAF 201/661 reads (30%) | catalogued as rs778237047; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMLN2 | c.1722C>T p.V574= | Silent (SNP) | VAF 38/618 reads (6%) | catalogued as rs1213304915; called by muse, mutect2
- MED16 | c.873G>A p.S291= | Silent (SNP) | VAF 56/293 reads (19%) | catalogued as rs372613097, COSV99516442; called by muse, mutect2, varscan2
- MGAM | c.3102C>T p.P1034= | Silent (SNP) | VAF 39/1666 reads (2%) | catalogued as rs758880313; called by muse, mutect2
- MICALL2 | c.2274C>T p.G758= | Silent (SNP) | VAF 41/591 reads (7%) | catalogued as rs1458420039; called by muse, mutect2
- MRPL40 | c.465G>A p.P155= | Silent (SNP) | VAF 150/300 reads (50%) | catalogued as rs150806674; called by muse, mutect2, varscan2
- MUC5B | c.16167G>A p.A5389= | Silent (SNP) | VAF 121/279 reads (43%) | catalogued as rs571777773, COSV71590500; called by muse, mutect2, varscan2
- MYH15 | c.4317C>T p.D1439= | Silent (SNP) | VAF 129/541 reads (24%) | catalogued as rs749790241; called by muse, mutect2, varscan2
- MYO3B | c.2043C>T p.D681= | Silent (SNP) | VAF 304/653 reads (47%) | catalogued as rs761027423, COSV58707750; called by muse, mutect2, varscan2
- NAV3 | c.2745C>T p.T915= | Silent (SNP) | VAF 96/679 reads (14%) | catalogued as rs989373030, COSV57075154, COSV57079662; called by muse, mutect2, varscan2
- NKAIN4 | c.624G>A p.A208= | Silent (SNP) | VAF 211/639 reads (33%) | catalogued as rs533476746, COSV53902541; called by muse, mutect2, varscan2
- NLRC3 | c.1041G>A p.T347= | Silent (SNP) | VAF 70/261 reads (27%) | catalogued as rs374944368; called by muse, mutect2, varscan2
- NLRP3 | c.171C>T p.I57= | Silent (SNP) | VAF 272/598 reads (45%) | catalogued as rs773673175, COSV60224096, COSV60229478; called by muse, mutect2, varscan2
- ODAPH | c.162G>A p.P54= | Silent (SNP) | VAF 437/885 reads (49%) | catalogued as rs755045480; called by muse, mutect2, varscan2
- OR2L3 | c.837C>A p.T279= | Silent (SNP) | VAF 163/704 reads (23%) | catalogued as rs761545937; called by muse, mutect2, varscan2
- OR4K2 | c.234C>G p.T78= | Silent (SNP) | VAF 40/652 reads (6%) | called by muse, mutect2
- PDZRN3 | c.2148C>T p.R716= | Silent (SNP) | VAF 40/522 reads (8%) | catalogued as rs1459238698, COSV55198321; called by muse, mutect2
- PHF6 | c.594G>A p.R198= (on ENST00000332070 / NM_032458.3; = p.R199= on NM_032335.3) | Silent (SNP) | VAF 220/368 reads (60%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.1257C>T p.Y419= | Silent (SNP) | VAF 139/526 reads (26%) | catalogued as rs776232557, COSV59535384; called by muse, mutect2, varscan2
- PKD1 | c.2073C>T p.P691= | Silent (SNP) | VAF 56/324 reads (17%) | catalogued as rs768088779; called by muse, mutect2, varscan2
- PXDN | c.1866G>A p.P622= | Silent (SNP) | VAF 46/938 reads (5%) | catalogued as rs751535853, COSV53227076; called by muse, mutect2
- QSOX1 | c.1413C>T p.N471= | Silent (SNP) | VAF 269/555 reads (48%) | catalogued as rs760465139, COSV62580417; called by muse, mutect2, varscan2
- RP1 | c.4473A>G p.E1491= | Silent (SNP) | VAF 68/1192 reads (6%) | catalogued as rs149597597; called by muse, mutect2
- RSPH10B2 | c.1575C>T p.T525= | Silent (SNP) | VAF 126/2078 reads (6%) | catalogued as rs764853526; called by muse, mutect2
- SBNO2 | c.2307G>A p.S769= | Silent (SNP) | VAF 285/658 reads (43%) | catalogued as rs1485052780; called by muse, mutect2, varscan2
- SCAF11 | c.3447C>T p.A1149= | Silent (SNP) | VAF 290/660 reads (44%) | catalogued as rs371897313; called by muse, mutect2, varscan2
- SCARF1 | c.1272C>T p.I424= | Silent (SNP) | VAF 144/582 reads (25%) | catalogued as rs780466544, COSV53959726; called by muse, mutect2, varscan2
- SH2B3 | c.204C>T p.T68= | Silent (SNP) | VAF 109/221 reads (49%) | called by muse, mutect2, varscan2
- SH2D5 | c.1209G>A p.P403= (on ENST00000444387 / NM_001103161.2; = p.P319= on NM_001103160.2) | Silent (SNP) | VAF 165/330 reads (50%) | catalogued as rs201881344, COSV99929766; called by muse, varscan2
- SLC9A8 | c.1581C>T p.F527= | Silent (SNP) | VAF 204/772 reads (26%) | catalogued as rs1441932016, COSV64287043; called by muse, mutect2, varscan2
- SRGAP2 | c.690G>A p.K230= | Silent (SNP) | VAF 294/1509 reads (19%) | catalogued as rs1553351405; called by muse, varscan2
- SYNE1 | c.5700C>T p.N1900= (on ENST00000367255 / NM_182961.4; = p.N1907= on NM_033071.3) | Silent (SNP) | VAF 146/661 reads (22%) | catalogued as rs1466517008, COSV54972119; called by muse, mutect2, varscan2
- SYNPO | c.2388C>T p.N796= (on ENST00000394243 / NM_001166208.2; = p.N552= on NM_007286.6) | Silent (SNP) | VAF 185/358 reads (52%) | catalogued as rs138232729; called by muse, mutect2, varscan2
- TBX2 | c.1068C>T p.C356= | Silent (SNP) | VAF 16/452 reads (4%) | catalogued as rs1216884550; called by muse, mutect2
- TRMT1 | c.549C>T p.N183= | Silent (SNP) | VAF 127/680 reads (19%) | catalogued as rs559922059, COSV52835422; called by muse, mutect2, varscan2
- VPREB1 | c.135C>T p.N45= | Silent (SNP) | VAF 221/513 reads (43%) | catalogued as rs754613086, COSV56425526; called by muse, mutect2, varscan2
- ZCCHC2 | c.975C>T p.N325= | Silent (SNP) | VAF 207/1270 reads (16%) | catalogued as rs774479120; called by muse, mutect2, varscan2
- ZEB2 | c.3288C>T p.R1096= | Silent (SNP) | VAF 485/1073 reads (45%) | catalogued as rs772712992, COSV57951001; called by muse, mutect2, varscan2
- ABI3BP | c.1577-12044G>A | Intron (SNP) | VAF 44/1484 reads (3%) | catalogued as rs1410406766, COSV52533908; called by muse, mutect2
- AFDN | chr6:167976714 del C | 3'Flank (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- C17orf107 | c.*12G>A | 3'UTR (SNP) | VAF 35/480 reads (7%) | catalogued as rs1017271148; called by muse, mutect2
- CD22 | c.1507+43G>A | Intron (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- EDNRA | c.*74G>A | 3'UTR (SNP) | VAF 23/321 reads (7%) | catalogued as COSV100163194; called by muse, mutect2
- EFCAB6 | c.3648+35C>T | Intron (SNP) | VAF 110/208 reads (53%) | catalogued as rs908195322; called by muse, mutect2, varscan2
- ELMOD2 | c.534-37C>T | Intron (SNP) | VAF 169/380 reads (44%) | catalogued as rs575335988; called by muse, mutect2, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 16/508 reads (3%) | called by muse, mutect2
- FAT1 | c.-12G>A | 5'UTR (SNP) | VAF 346/733 reads (47%) | catalogued as rs1264380184; called by muse, mutect2, varscan2
- FNDC1 | c.668-3203G>A | Intron (SNP) | VAF 51/101 reads (50%) | catalogued as rs755778261; called by muse, mutect2, varscan2
- GRB10 | c.52-6974G>A | Intron (SNP) | VAF 208/768 reads (27%) | catalogued as rs752904531, COSV100241392; called by muse, mutect2, varscan2
- HOOK2 | c.1938+12C>T | Intron (SNP) | VAF 144/280 reads (51%) | catalogued as rs1423597500; called by muse, mutect2, varscan2
- HPCAL1 | c.*6C>T | 3'UTR (SNP) | VAF 92/542 reads (17%) | catalogued as rs375284056; called by muse, mutect2, varscan2
- JAK3 | c.*66G>A | 3'UTR (SNP) | VAF 176/355 reads (50%) | called by muse, mutect2, varscan2
- LAX1 | c.-188G>A | 5'UTR (SNP) | VAF 38/817 reads (5%) | catalogued as rs996189843; called by muse, mutect2
- LINC02054 | n.2489G>A | RNA (SNP) | VAF 44/640 reads (7%) | catalogued as rs1010490875; called by muse, mutect2
- MAPKAPK2 | c.1059+143G>A | Intron (SNP) | VAF 33/935 reads (4%) | catalogued as rs782092001, COSV99686172; called by muse, mutect2
- MEN1 | c.1064+95G>A | Intron (SNP) | VAF 21/43 reads (49%) | catalogued as rs186166743; called by muse, mutect2, varscan2
- MPND | c.7+34_7+35insTGCAGGGGC | Intron (INS) | VAF 5/265 reads (2%) | catalogued as rs780729953; called by mutect2, varscan2*
- NAT14 | c.*58C>T | 3'UTR (SNP) | VAF 51/176 reads (29%) | catalogued as rs933559450; called by muse, mutect2, varscan2
- PANK4 | c.*4G>A | 3'UTR (SNP) | VAF 18/584 reads (3%) | catalogued as rs745765431, COSV53941385; called by muse, mutect2
- PDCD11 | c.564+17G>A | Intron (SNP) | VAF 258/553 reads (47%) | catalogued as rs371338306; called by muse, mutect2, varscan2
- PDE4DIP | c.5651-54G>A | Intron (SNP) | VAF 65/206 reads (32%) | catalogued as rs1411436413; called by muse, mutect2, varscan2
- PTGS2 | c.*35C>A | 3'UTR (SNP) | VAF 43/294 reads (15%) | called by muse, mutect2, varscan2
- PUF60 | c.603+30G>A | Intron (SNP) | VAF 15/320 reads (5%) | catalogued as rs553094700, COSV57589646; called by muse, mutect2
- RIMBP2 | c.*1606T>C | 3'UTR (SNP) | VAF 51/921 reads (6%) | called by muse, mutect2
- SCAF4 | c.777+20C>T | Intron (SNP) | VAF 274/605 reads (45%) | called by muse, mutect2, varscan2
- SLC25A25 | chr9:128068258 C>T | 5'Flank (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- SRP68 | c.*20C>T | 3'UTR (SNP) | VAF 181/357 reads (51%) | catalogued as rs575532025, COSV57162978; called by muse, mutect2, varscan2
- SSPOP | n.13467G>A | RNA (SNP) | VAF 33/593 reads (6%) | catalogued as rs576522892; called by muse, mutect2
- THOC6 | c.362+15G>A | Intron (SNP) | VAF 26/566 reads (5%) | catalogued as rs1469178876; called by muse, mutect2
- TSC2 | c.2838-26G>A | Intron (SNP) | VAF 183/422 reads (43%) | catalogued as rs750859415; called by muse, mutect2, varscan2
- TSGA13 | c.-76C>T | 5'UTR (SNP) | VAF 78/395 reads (20%) | catalogued as rs529219247, COSV63019119; called by muse, mutect2, varscan2
- ZIC4 | c.71-34C>A | Intron (SNP) | VAF 24/128 reads (19%) | called by muse, varscan2
